Gene-level copy-number profile of tumor specimen TCGA-2J-AABI-01A from TCGA case TCGA-2J-AABI, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 55.6 years (20,316 days).
Specimen TCGA-2J-AABI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.d278f991-9064-4e6d-b6d0-f2e8becd19fd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2J-AABI-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1ebee982-52ce-475a-bb41-b3446f482487

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 19,101; copy number 2: 39,859; copy number 3: 2; copy number 5: 3; copy number 6: 850.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2J-AABI-01A-12D-A40V-01): tumor purity 0.72, ploidy 1.75, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 853 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:84,881,984–84,947,061, 2 genes, copy number 5: LINC02025, AC132660.2.
- chr3:85,385,710–85,385,792, 1 gene, copy number 5: MIR5688.
- chr12:66,767–34,249,958, 850 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 19,101. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
